CCDI case PBCDMK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/e572953f-8c44-4774-a536-d7e3419bbb2b

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 1.7 years (639 days).

Biospecimens (3 samples)
- Sample 0DPUTG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPUTK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPUTT: Tissue type: Tumor; Specimen type: Solid Tissue.
